FM case AD3248 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/750dd2c0-9af9-4f8b-b9ab-2015002e37dd

Male, 66.8 years: Spindle cell carcinoma, NOS (ICD-O-3 8032/3) of the head, face or neck; specimen biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Tumor.
